Surgical pathology report (de-identified scan), TCGA case TCGA-N8-A4PP, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of North Carolina, specimen TCGA-N8-A4PP-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

IED 0-3
Carcinosarcoma, NOS
898013
Site: Endometrium
C54.1
12/14/12 JW

Diagnosis:

A: Uterus and cervix, bilateral ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy

Location of tumor: anterior and posterior endometrium extending into anterior and posterior lower uterine segment and invasive carcinoma also involves the posterior upper endocervix (A18)

Tumor size: 6.5 x 6.4 x 4.5 cm per gross measurement of carcinoma within the endometrium and a large amount of disrupted tumor is also received separately (9.2 x 8.9 x 3.0 cm) (see comment)

Histologic type: Carcinosarcoma, with serous carcinoma and homologous sarcomatous component (see comment)

Histologic grade (FIGO): FIGO grade 3

Extent of invasion:

Myometrial invasion: outer half

Depth: 6.5 mm Wall thickness: 1.3 cm Percent: 50% (A6)

Serosal involvement: not identified

Lower uterine segment involvement: Present. Invasive serous carcinoma involves anterior and posterior lower uterine segments.

Cervical involvement: Present. Invasive serous carcinoma involves stroma of posterior upper endocervix, invading to a depth of 3 mm, in area with cervical wall thickness of 1.0 cm (33%) (A18)

Adnexal involvement (see below): not identified

Other sites: not applicable

Cervical margin and distance: Negative. Invasive carcinoma is 7 mm from cervical wall margin (A18). Length of endocervical canal is 4.5 cm.

Lymphovascular space invasion: present

[page 2 of 6]
Regional lymph nodes (see other specimens): See Specimen B

Total number involved: 1

Total number examined: 1

Other pathologic findings:

- Cervix with mild acute and chronic cervicitis, Nabothian cyst, tubal metaplasia and tunnel clusters
- Hyalinized leiomyomata, size 3.2 cm in greatest dimension
- Background atrophic endometrium with chronic endometritis
- Vessels with medial calcification
- Perineural invasion present

Right ovary

- Atrophic with epithelial inclusion glands, and medial calcification of vessels
- No malignancy identified

Left ovary

- Atrophic with epithelial inclusion glands and dystrophic calcifications
- No malignancy identified

Right fallopian tube

- Mild chronic salpingitis
- No malignancy identified

Left fallopian tube

- Acute salpingitis
- Fibrous serosal adhesions
- No malignancy identified

AJCC Pathologic Stage: pT 2 pN1

FIGO (2008 classification) Stage grouping: IIIC1

B: Lymph nodes, right pelvic, regional resection

- One lymph node positive for metastatic serous carcinoma, size 6.2 cm with no definite extracapsular extension identified in focally disrupted tissue (1/1)
- See comment

Comment:

The hysterectomy specimen is received disrupted at the junction

[page 3 of 6]
Representative sections show predominantly serous carcinoma. Additional representative sections are submitted and one shows a sarcomatous component (A17). Previous biopsy also shows carcinosarcoma with homologous type

The findings are consistent with carcinosarcoma with serous carcinomatous component and homologous sarcomatous component.

Immunohistochemistry stains have been added on (A17) and an addendum will be issued with the result.

-year-old female with endometrial cancer.

Received are two appropriately labeled containers.

Adnexa: present, bilaterally attached

Shape: pyriform

height: 15.0 cm

anterior to posterior width: 6.8 cm

breadth at fundus: 9.4 cm

Serosa: tan/brown, smooth and glistening with dark red/brown discoloration; there is gray/white speckling along the posterior serosa

ectocervix: brown/pink, smooth and glistening

endocervix: tan, trabeculated; The cervix was received disrupted and tattered; The anterior cervix is connected to the posterior cervix, but is not connected to the anterior lower uterine segment.

length of endocervical canal: 4.5 cm long, 2.6 cm wide

[page 4 of 6]
Endomyometrium:

length of endometrial cavity: 8.0 cm
width of endometrial cavity at fundus: 5.5 cm

tumor findings:

dimensions: 6.5 x 6.4 x 4.5 cm protruding into the cavity with a separate aggregate of tumor fragments within the accompanying container (9.2 x 8.9 x 3.0 cm)
appearance: tan/yellow, friable and fungating
location and extent: it involves the anterior and posterior endometrial cavity, extends into the posterior lower uterine segment, 0.2 cm from the endocervical canal
myometrial invasion: inner one-half thickness of myometrial wall at deepest gross invasion: 1.5 cm
other findings or comments: There is a 3.2 x 2.8 x 2.2 cm homogeneous white whorled intramural nodule

Adnexa:

Right ovary:

dimensions: 2.5 x 2.8 x 0.6 cm
external surface: grossly unremarkable
cut surface: grossly unremarkable

Right fallopian tube:

dimensions: 4.2 cm long, 0.5 cm in diameter
other findings: The serosa is tan, smooth and glistening; the fimbria is focally discolored gray/white; The mucosa is unremarkable.

Left ovary:

dimensions: 2.6 x 1.0 x 0.7 cm
external surface: grossly unremarkable
cut surface: grossly unremarkable

Left fallopian tube:

dimensions: 5.5 cm long, 0.5 cm in diameter
other findings: The tube was received discontinuance. The serosa is tan/gray, smooth and glistening. The proximal mucosa is tan/brown and friable.
Lymph nodes: none

Other comments: none

Digital photograph taken: no

Tissue submitted for special investigations: tumor submitted to Tumor Procurement Foundation

Block summary:

- A1 - anterior cervix
- A2 - posterior cervix

[page 5 of 6]
A3,A4 - anterior corpus with mass and intramural nodule, full thickness, bisected
A5 - posterior corpus, full thickness, with mass
A6,A7 - longitudinal posterior lower uterine segment with mass
A8 - longitudinal anterior lower uterine segment with mass
A9 - right ovary and right fallopian tube, cross sections
A10-A12 - longitudinal section of right fallopian tube and remaining fimbria

A13 - left ovary and left fallopian tube, cross sectioned
A14 - longitudinal section of left fallopian tube and remaining fimbria
A15,A16 - anterior lower uterine segment, full thickness, bisected; possible perpendicular section
A17,A18 - posterior lower uterine segment, perpendicular section, bisected
A19 - posterior cervix
A20-A24 - representative sections of mass, unoriented
Tissue remains in formalin.

Container B is additionally labeled "right pelvic." It contains a 6.2 x 5.0 x 3.4 cm tan/gray nodular firm mass. The mass is focally disrupted and the remainder is surrounded by a smooth capsule which is less than 0.1 cm in thickness. A portion of the mass was given to the Tumor Procurement foundation.

Block summary:

B1,B2 - each contain a representative section of mass

Grossing Pathologist:, MD

Light Microscopy:

Light microscopic examination performed by Dr.

The majority of the tumor is poorly differentiated carcinoma (serous carcinoma).

Additional representative sections are taken and one slide (A17) shows a sarcomatous component. Immunohistochemistry is pending on this section and an addendum will be issued with the result. Also, the prior outside biopsy shows carcinosarcoma with homologous type . The findings are consistent with carcinosarcoma, with serous carcinomatous component and homologous sarcomatous component.

[page 6 of 6]
For cases in which immunostains are performed, the following applies:

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by . These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Procedures/Addenda:

Addendum

Addendum

For immunohistochemistry stains

Addendum Comment

Immunostains are performed on the representative section with sarcomatous component by morphology (A17) .

Pancytokeratin: positive in carcinoma, negative in sarcoma

Vimentin: negative in carcinoma; positive in sarcoma

Desmin: negative in carcinoma; focally positive in sarcoma

Smooth muscle actin: negative in carcinoma; subset positive in sarcoma

Muscle specific actin: negative in carcinoma; subset positive in sarcoma

The findings are supportive of carcinosarcoma with homologous sarcomatous component. The previous diagnoses are unchanged.

	Yes	No
Accuracy		X
breast	X	X
Reviewed: 12/12/12		

KMP

Source: NCI Genomic Data Commons file 6324ba81-d99e-4466-ab27-dccc7d48718b (TCGA-N8-A4PP.0DB7C027-8B7F-422C-8B0A-8B71CB972119.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).